Gene-level copy-number profile of tumor specimen TCGA-UF-A71A-01A from TCGA case TCGA-UF-A71A, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 67.4 years (24,623 days).
Specimen TCGA-UF-A71A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.49688509-b237-48af-960c-c1cc0b86b75c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UF-A71A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2026ffc1-52b9-486d-90d2-8e41353fce3d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 595; copy number 2: 16,752; copy number 3: 21,534; copy number 4: 12,415; copy number 5: 3,389; copy number 6: 2,638; copy number 7: 1,734; copy number 8: 51; copy number 9: 650; copy number 12: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UF-A71A-01A-22D-A34I-01): tumor purity 0.68, ploidy 3.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:18,979,619–19,000,952, 2 genes (within-gene range 0–2): SNORA62, AC009884.1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr10:60,684,505–60,741,828, 2 genes (within-gene range 0–2): ARL4AP1, ANK3-DT.
- chr13:110,340,958–110,341,029, 1 gene: MIR8073.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,475 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:158,962,235–159,897,366, 1 gene, copy number 8 (within-gene range 5–8): IQCJ-SCHIP1.
- chr3:159,282,646–198,222,513, 686 genes, copy number 8–9 (broad region; genes not listed).
- chr7:136,485,656–144,451,817, 295 genes, copy number 7 (broad region; genes not listed).
- chr18:2,967,018–3,478,978, 19 genes, copy number 9–12: AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,571,215–3,608,336, 4 genes, copy number 9: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2.
- chr19:53,775,599–54,339,162, 51 genes, copy number 7 (within-gene range 5–7): AC008753.1, AC008753.3, MIR371A, MIR371B, MIR372, MIR373, AC008753.2, NLRP12, MYADM-AS1, MYADM, AC008440.1, PRKCG, CACNG7, CACNG8, MIR935, CACNG6, AC012314.9, VSTM1, TARM1, OSCAR, NDUFA3, TFPT, PRPF31, AC245052.4, CNOT3, LENG1, TMC4, MBOAT7, TSEN34, AC245052.1, RPS9, AC245052.2, LILRB3, AC245052.7, AC245052.3, LILRA6, AC245052.6, LILRB5, RNU6-1307P, AC245052.5, LILRB2, MIR4752, AC245884.5, AC245884.12, AC245884.7, AC245884.2, LILRA5, AC245884.11, VN1R104P, AC245884.6, LILRA4.
- chr20:87,250–2,866,732, 94 genes, copy number 7 (broad region; genes not listed).
- chr22:16,671,090–50,801,309, 1,325 genes, copy number 7–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 595. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
